Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A4QV, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A4QV-01A (Primary Tumor).

[page 1 of 2]
AP Surgical Pathology:

Surg Path

CLINICAL HISTORY:

Endometrial cancer. year old PO uterine cancer, MMTV. PO adenocarcinoma.

GROSS EXAMINATION:

A. "Uterus, cervix (AF1-AF2)". Received fresh is a 186 gram, 11.5 x 7.3 x 5.5 cm uterus. The red-tan, smooth, glistening, focally erythematous serosa discloses a single 0.5 x 0.5 cm red-tan nodule surrounded a focus of hemorrhage. The opened specimen discloses a 0.8 x 0.6 cm gray-tan polyp on the anterior endocervix 0.4 cm from the external os (Frozen AF2, remnant A2). The posterior endocervix harbors a 0.6 x 0.6 cm tan-pink nodule 2.4 cm from the external os. The endometrial cavity is occupied by a 6.0 x 3.5 x 1.0 cm tan-brown, polypoid tumor that has arisen from the anterior wall. On section, the tumor is smooth, tan-brown, and focally hemorrhagic (Frozen AF1, remnant A1). It penetrates 0.1 cm into the 2.3 cm thick myometrium. The posterior endometrium contains a 0.6 x 0.6 x 0.3 cm red-tan polyp near the fundus, and a 0.7 x 0.3 x 0.2 cm tan-brown polyp, 2.0 cm from the endocervical canal. The residual endometrium is pink-tan and 0.1 cm thick. The myometrium is pink-tan, trabeculated, and contains a 0.5 x 0.4 cm white-tan, intramural leiomyoma.

BLOCK SUMMARY:

- A1- tumor, frozen section remnant.
- A2- cervix, frozen section remnant.
- A3- anterior cervix.
- A4- anterior lower uterine segment.
- A5- tumor with deepest invasion (endometrial half).
- A6- deepest invasion (serosal half).
- A7-A12 tumor.
- A13- leiomyoma, anterior.
- A14- posterior cervix.
- A15- posterior lower uterine segment with nodule.
- A16- posterior endomyometrium with polyp.
- A17- posterior endomyometrium.
- A18- nodule on serosa.

ICD-0-3

Carcinosarcoma, NOS 8090/3

Site: Corpus Uteri C54.9

Copied AUS 1/6/13

B. "Right tube and ovary". Received fresh is a 10.7 gram, 4.5 x 3.7 x 1.5 cm fallopian tube and ovary. The fallopian tube is 3.5 cm long, and 0.6 cm in diameter. The lumen is pin point (B1). The 2.2 x 1.4 x 1.1 cm ovary is diffusely surrounded by a 3.0 x 2.0 cm area of mesenteric hemorrhage (B2). The sectioned cut surface is unremarkable.

C. "Left tube and ovary". Received fresh is a 9.9 gram, 4.0 x 3.5 x 1.7 cm fallopian tube and ovary. The fallopian tube is 5.0 cm long, and 0.7 cm in diameter. The lumen is pin point (C1). Multiple 6 mm paratubal cysts are present. The 3.0 x 1.2 x 0.7 cm ovary is unremarkable (C2).

D. "Omentum". Received fresh is a 4.5 x 4.0 x 1.0 cm aggregate of yellow-tan fibroadipose tissue, which on section is tan, lobulated and focally hemorrhagic (D1).

E. "Left external iliac node", received fresh and placed in formalin. A 4.5 x 2.0 x 1.2 cm fragment of yellow-brown fibroadipose tissue containing lymph node candidate is received. Four lymph node candidates are submitted in block E1, one lymph node candidate is submitted in block E2, and one lymph node candidate is submitted in block E3.

F. "Left pelvic node", received fresh and placed in formalin. A 4.5 x 2.5 x 0.5 cm aggregate of yellow-tan fibroadipose tissue containing lymph node

[page 2 of 2]
candidate is received. Two lymph node candidates are submitted in block F1.

G. "Right pelvic", received fresh and placed in formalin. A 6.0 x 4.0 x 1.5 cm aggregate of yellow-tan fibroadipose tissue containing lymph node candidate is received. Six lymph node candidates are submitted in block G1, four lymph node candidates are submitted in block G2, and one lymph node candidate is submitted in block G3.

INTRA OPERATIVE CONSULTATION:

A. "Uterus, cervix":

AF1- Fundus mass. Carcinosarcoma,
Superficially invasive at most
AF2 Cervical polyp: Cervix positive for tumor.
Mucosal only, no stromal invasion seen.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. UTERUS: 186 GRAMS

ENDOMETRIUM:

TUMOR SITE: CORPUS

HISTOLOGY: CARCINOSARCOMA

TUMOR DIMENSIONS: 6.0 X 3.5 X 1.0 CM.

DEPTH OF INVASION: LESS THAN 2 MM, IN A 2.3 CM THICK WALL.

LYMPHATIC/VASCULAR INVASION: NONE

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: ABSENT

MYOMETRIUM: LEIOMYOMA, SMALL

CERVIX: NODULE OF TUMOR ON MUCOSA; NOT INVASIVE INTO WALL.

SEROSA: ADHESIONS

THE FOLLOWING ARE FREE OF TUMOR

B. RIGHT OVARY: DENSE ADHESIONS

RIGHT FALLOPIAN TUBE: NO PATHOLOGIC DIAGNOSIS.

C. LEFT OVARY AND FALLOPIAN TUBE

D. OMENTUM

E. LEFT EXTERNAL ILIAC LYMPH NODES: NO TUMOR IN 7 LYMPH NODES (0/7).

F. LEFT PELVIC LYMPH NODES: NO TUMOR IN 2 LYMPH NODES (0/2).

G. RIGHT PELVIC LYMPH NODES: NO TUMOR IN 7 LYMPH NODES (0/7).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

HPA Discrepancy		☒
Case is Final	☒	☐
Reviewed by	☒	☐

Source: NCI Genomic Data Commons file 698e23ce-1f0d-4531-b050-cf8bb714ed33 (TCGA-NA-A4QV.B2A672EA-7D36-4634-A52E-45BAE2F93D0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).